HCMI case HCM-BROD-0483-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d7426469-359e-45e4-a58a-f70e4147cd10

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1968; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,303 days); Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 164 days; Days to treatment end: 164 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 50.6 years (18,472 days); Days to diagnosis: 169 days.
3. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 50.7 years (18,516 days); Days to diagnosis: 213 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cabozantinib + Pembrolizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 164 days; Days to treatment end: 170 days.

Follow-up (2 entries)
- Days to follow up: 213 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 211.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 48 kg; Height: 157 cm; BMI: 19.5.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0483-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0483-C16-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0483-C16-06A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0483-C16-07A: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0483-C16-07A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0483-C16-07A-01-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0483-C16-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0483-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
- Sample HCM-BROD-0483-C16-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
